Somatic mutation profile of tumor specimen MP2PRT-PAUUFR-TMP1-A (aliquot MP2PRT-PAUUFR-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAUUFR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.2 years (2,621 days).
Specimen MP2PRT-PAUUFR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1678f274-88eb-46bc-b302-297b91a77a3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUUFR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUUFR-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5e77f01-e2fc-453a-9a60-6602ed306302

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Frame Shift Ins 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM18 | c.1365T>G p.D455E | Missense Mutation (SNP) | VAF 45/438 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV55847435; called by muse, mutect2, varscan2
- DBX1 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 20/666 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV57053787; called by muse, mutect2
- FSIP2 | c.10211G>A p.R3404Q | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs564239040; called by muse, mutect2, varscan2
- ANKRD60 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2
- ATRNL1 | c.1362G>T p.W454C | Missense Mutation (SNP) | VAF 117/265 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by mutect2, varscan2
- IGKV1OR2-108 | chr2:113406860 ATACTACCCCATTCACAGTGTT>CCCCGG | Missense Mutation (DEL) | VAF 54/216 reads (25%) | called by pindel, varscan2*
- KCNK3 | c.1017dup p.V340Rfs*298 | Frame Shift Ins (INS) | VAF 158/644 reads (25%) | called by mutect2, pindel, varscan2
- ODF3B | c.183_184insCTTT p.T62Lfs*207 | Frame Shift Ins (INS) | VAF 201/894 reads (22%) | called by mutect2, pindel*, varscan2*
- TTC6 | c.2909C>T p.A970V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XRCC4 | c.768C>T p.S256= | Silent (SNP) | VAF 42/197 reads (21%) | called by muse, mutect2, varscan2
